CCDI case PBCFTE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/381e82ae-3ee0-4b3f-b517-d9c64215f4c1

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Biospecimens (3 samples)
- Sample 0DR1XI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR1YT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR1ZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
